CPTAC case C3L-00927 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a11e9ea9-8036-4145-91c0-61f833dc5db4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 74.4 years (27,187 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,777 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,777 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 5 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 17; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 361 days; Disease response: Tumor Free.
- Days to follow up: 678 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,057 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,432 days (3.9 years); Disease response: Complete Response.
- Days to follow up: 1,432 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,777 days (4.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 93 kg; Height: 188 cm; BMI: 26.31; DLCO (% of predicted): 71; FEV1/FVC after bronchodilator (%): 62; FEV1/FVC before bronchodilator (%): 60; FEV1 after bronchodilator (% of reference): 67; FEV1 before bronchodilator (% of reference): 64.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 57; Cigarettes per day: 20; Tobacco smoking onset year: 1959; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 63.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00927-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 219 mg.
- Sample C3L-00927-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 408 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00927-22: Section location: Left Lower Lobe; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3L-00927-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 274 mg.
- Sample C3L-00927-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 271 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00927-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
